Somatic mutation profile of tumor specimen TCGA-UF-A719-01A (aliquot TCGA-UF-A719-01A-12D-A34J-08) from TCGA case TCGA-UF-A719, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 54.2 years (19,797 days).
Specimen TCGA-UF-A719-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dc16fc8-3ab5-40bf-9119-65d6d181b67d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A719-10A (Blood Derived Normal), aliquot TCGA-UF-A719-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d52831b2-71dd-478c-9e1e-210630c0d384

The open-access MAF lists 121 somatic variants for this specimen: 88 protein-altering or splice-affecting, 29 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 29, Frame Shift Del 4, Splice Site 3, Nonsense Mutation 2, 5'UTR 2, 3'UTR 1, Frame Shift Ins 1, Translation Start Site 1, Intron 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 37/108 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD1 | c.941T>G p.I314R | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV99574597; called by muse, mutect2, varscan2
- ACE2 | c.218T>C p.L73S | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV99382940; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs1172330874, COSV55000338; called by muse, mutect2, varscan2
- AKNAD1 | c.1551C>A p.H517Q | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV100645391, COSV100645666; called by muse, mutect2, varscan2
- ASH1L | c.7874G>C p.C2625S (on ENST00000368346 / NM_001366177.2; = p.C2620S on NM_018489.3) | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100853490; called by muse, mutect2
- BMPR1B | c.143+1G>A p.X48_splice | Splice Site (SNP) | VAF 21/95 reads (22%) | catalogued as COSV52777963, COSV99216036; called by muse, mutect2, varscan2
- BRWD1 | c.2530G>A p.E844K | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV100313646; called by muse, mutect2
- CADPS | c.1526A>C p.K509T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.398); catalogued as COSV99339324; called by muse, mutect2, varscan2
- CDH9 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178482472, COSV99146072; called by muse, mutect2, varscan2
- CEP192 | c.6269C>G p.S2090C | Missense Mutation (SNP) | VAF 32/414 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV58072673; called by muse, mutect2
- CHD3 | c.5755G>A p.A1919T (on ENST00000330494 / NM_001005273.3; = p.A1885T on NM_005852.4) | Missense Mutation (SNP) | VAF 29/464 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.015); catalogued as COSV100177216; called by muse, mutect2
- CLPTM1 | c.1554C>T p.F518= | Splice Region (SNP) | VAF 97/136 reads (71%) | catalogued as rs751995007, COSV61611923; called by muse, mutect2, varscan2
- CNOT7 | c.773A>G p.H258R | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV100778553; called by muse, mutect2
- COBL | c.3256C>G p.P1086A | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99473132; called by muse, mutect2, varscan2
- COLEC11 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs139848694; called by muse, mutect2, varscan2
- CPS1 | c.3756G>C p.L1252F | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV99242879; called by muse, mutect2
- CSMD3 | c.5318T>A p.V1773D (on ENST00000297405 / NM_001363185.1; = p.V1669D on NM_052900.3) | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99838531; called by muse, mutect2, varscan2
- DGAT1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1342245507, COSV100184079; called by muse, mutect2, varscan2
- DGAT2 | c.941T>C p.F314S | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99929870; called by muse, mutect2, varscan2
- DNAH9 | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV99306589; called by muse, mutect2, varscan2
- DPP10 | c.366+2T>A p.X122_splice | Splice Site (SNP) | VAF 12/146 reads (8%) | catalogued as COSV100068290; called by muse, mutect2
- DSG1 | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99936203; called by muse, mutect2, varscan2
- EIF2AK1 | c.623G>A p.C208Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV99552065; called by muse, mutect2
- FAM193A | c.3766A>T p.S1256C (on ENST00000324666 / NM_001256666.1; = p.S1215C on NM_003704.3) | Missense Mutation (SNP) | VAF 201/434 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100219350; called by muse, mutect2, varscan2
- FNBP4 | c.1790C>T p.T597I | Missense Mutation (SNP) | VAF 86/144 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99771795; called by muse, mutect2, varscan2
- FSTL5 | c.1884A>T p.K628N | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60220481; called by muse, mutect2, varscan2
- GABPA | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT tolerated, low confidence (0.91); PolyPhen possibly damaging (0.84); catalogued as COSV100702467; called by muse, mutect2, varscan2
- GOLGA5 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99371052; called by muse, mutect2, varscan2
- GRIN2A | c.4184C>T p.A1395V | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs199696775, COSV58054811; called by muse, mutect2, varscan2
- H3C11 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV100137770; called by muse, mutect2, varscan2
- HIVEP1 | c.149G>C p.R50P | Missense Mutation (SNP) | VAF 77/494 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179938140, COSV101045302, COSV65105993; called by muse, mutect2, varscan2
- ITPR2 | c.7550G>A p.R2517Q | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1053935118, COSV101190052; called by muse, mutect2, varscan2
- KATNIP | c.1744G>A p.D582N | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as rs1405422932, COSV99851446; called by muse, mutect2, varscan2
- KCNQ4 | c.1763G>A p.G588D | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1248614084, COSV100714367; called by muse, mutect2, varscan2
- KHDC4 | c.940A>C p.N314H | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100850826; called by muse, mutect2, varscan2
- KIAA0753 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.349); catalogued as COSV100810630; called by muse, mutect2, varscan2
- KLF5 | c.425A>G p.D142G | Missense Mutation (SNP) | VAF 52/416 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100890564; called by muse, mutect2, varscan2
- LAMB1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV55967599; called by muse, mutect2, varscan2
- LNPEP | c.1049A>G p.E350G | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.511); catalogued as COSV99183557; called by muse, mutect2, varscan2
- LRBA | c.7652A>G p.H2551R | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100841834; called by muse, mutect2, varscan2
- MAP4K4 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV100155267; called by muse, mutect2, varscan2
- MARCHF3 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs778125453, COSV58037601; called by muse, mutect2, varscan2
- MCC | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs775881721, COSV100202500; called by muse, mutect2, varscan2
- NEDD8 | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99164640; called by muse, mutect2, varscan2
- NSD1 | c.4583C>A p.S1528Y | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100729516; called by muse, mutect2, varscan2
- NTN4 | c.1368C>A p.D456E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV100643796; called by muse, mutect2, varscan2
- OR4M1 | c.140G>T p.C47F | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60062347; called by muse, mutect2, varscan2
- OR56B1 | c.614G>C p.S205T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV100402655; called by muse, mutect2, varscan2
- PDHA1 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100135051; called by muse, mutect2, varscan2
- PKHD1L1 | c.6874G>A p.G2292S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749307108, COSV101006467; called by muse, mutect2, varscan2
- PLCB4 | c.3527G>C p.*1176Sext*39 (on ENST00000278655 / NM_182797.3; = p.M1188I on NM_000933.4 and 2 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV53803917, COSV99595989; called by muse, mutect2, varscan2
- PYGO1 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs780685282, COSV100114720; called by muse, mutect2, varscan2
- RAB3GAP2 | c.818T>C p.M273T | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV99424824; called by muse, mutect2, varscan2
- RESF1 | c.4829A>G p.D1610G | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs754685903, COSV100440426; called by muse, mutect2, varscan2
- RNF111 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs752094006, COSV100789105; called by muse, mutect2, varscan2
- RNF213 | c.6265C>T p.R2089W | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775006151, COSV100301009; called by muse, mutect2
- SAR1A | c.405A>C p.K135N | Missense Mutation (SNP) | VAF 48/395 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as COSV100951560; called by muse, mutect2, varscan2
- SCAMP3 | c.818C>T p.T273I | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0.01); catalogued as COSV100226794; called by muse, mutect2, varscan2
- SCFD2 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV101189416; called by muse, mutect2, varscan2
- SCN5A | c.3206C>T p.T1069M | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs199473187, CM055518, COSV61122207; ClinVar: likely benign / uncertain significance / not provided; called by muse, mutect2, varscan2
- SEC16B | c.2870C>A p.S957* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100381712, COSV57629441; called by muse, mutect2
- SECISBP2 | c.2498G>C p.G833A | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100358534; called by muse, mutect2, varscan2
- SLC22A16 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100397558, COSV57927190; called by muse, mutect2, varscan2
- SLC45A1 | c.1750G>A p.A584T | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs772289747, COSV99239167, COSV99239646; called by muse, mutect2, varscan2
- SLC4A4 | c.1780T>C p.F594L (on ENST00000264485 / NM_001098484.3; = p.F550L on NM_003759.4) | Missense Mutation (SNP) | VAF 65/178 reads (37%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.946); catalogued as COSV99140597; called by muse, mutect2, varscan2
- SPATA31E1 | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as COSV100350664; called by muse, mutect2, varscan2
- SYNE1 | c.13741G>C p.A4581P (on ENST00000367255 / NM_182961.4; = p.A4510P on NM_033071.3) | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99569907; called by muse, mutect2, varscan2
- TMCO5A | c.807G>T p.K269N | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV100148611; called by muse, mutect2, varscan2
- TOM1L1 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.185); catalogued as COSV100779242; called by muse, mutect2, varscan2
- TRIM23 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs772713581, COSV99140094; called by muse, mutect2, varscan2
- TRIM23 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.01); catalogued as COSV99140097; called by muse, mutect2, varscan2
- TSHZ2 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100296336; called by muse, mutect2, varscan2
- UBTF | c.1801G>A p.G601S | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as COSV57187082; called by muse, mutect2, varscan2
- USH2A | c.7121-1G>T p.X2374_splice | Splice Site (SNP) | VAF 52/178 reads (29%) | catalogued as COSV100237789; called by muse, mutect2, varscan2
- VTI1A | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV101261369; called by muse, mutect2, varscan2
- WWP1 | c.2462A>G p.Y821C | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616674; called by muse, mutect2, varscan2
- XKR9 | c.27G>T p.M9I | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101281948; called by muse, mutect2, varscan2
- ZNF521 | c.1955A>G p.H652R | Missense Mutation (SNP) | VAF 29/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100832620; called by muse, mutect2, varscan2
- ZNF675 | c.331T>C p.F111L | Missense Mutation (SNP) | VAF 14/274 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100705102; called by muse, mutect2
- ZNF792 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68693956; called by muse, mutect2, varscan2
- ZZZ3 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 30/181 reads (17%) | catalogued as COSV100890363; called by muse, mutect2, varscan2
- GAS2L2 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPDL | c.735_739del p.E246Tfs*3 | Frame Shift Del (DEL) | VAF 20/110 reads (18%) | called by mutect2, pindel, varscan2
- KRT80 | c.829dup p.Q277Pfs*55 | Frame Shift Ins (INS) | VAF 39/101 reads (39%) | called by mutect2, pindel, varscan2
- RIOK2 | c.453_456del p.S154Vfs*5 | Frame Shift Del (DEL) | VAF 56/193 reads (29%) | called by mutect2, pindel, varscan2
- SALL4 | c.1051_1064del p.V351Ifs*30 | Frame Shift Del (DEL) | VAF 29/110 reads (26%) | called by mutect2, pindel, varscan2
- TCFL5 | c.1111del p.A371Pfs*53 | Frame Shift Del (DEL) | VAF 15/144 reads (10%) | called by mutect2, pindel, varscan2
- ABCB11 | c.1707C>T p.I569= | Silent (SNP) | VAF 50/113 reads (44%) | catalogued as rs773712534, COSV55596748; called by muse, mutect2, varscan2
- AKAP12 | c.2136G>A p.Q712= | Silent (SNP) | VAF 84/184 reads (46%) | catalogued as COSV99483758; called by muse, mutect2, varscan2
- ALG5 | c.147C>A p.A49= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV99523715; called by muse, mutect2, varscan2
- CAPN5 | c.2004C>T p.A668= (on ENST00000456580; = p.A628= on NM_004055.5) | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs200719609, COSV99582307; called by muse, mutect2, varscan2
- CFH | c.2748C>T p.Y916= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV100809819; called by muse, mutect2
- CUBN | c.5499C>A p.I1833= | Silent (SNP) | VAF 25/333 reads (8%) | catalogued as COSV100913017; called by muse, mutect2
- DAB2IP | c.15C>T p.S5= | Silent (SNP) | VAF 22/167 reads (13%) | catalogued as rs936282742, COSV52266614; called by muse, mutect2, varscan2
- DMRTB1 | c.690C>T p.G230= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as rs544350331, COSV101008359; called by muse, mutect2, varscan2
- EIF4A1 | c.459C>T p.H153= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs746334111, COSV99549046; called by muse, mutect2
- EPX | c.516C>T p.P172= | Silent (SNP) | VAF 30/48 reads (63%) | catalogued as rs1377424147, COSV99836612; called by muse, mutect2, varscan2
- GALNT6 | c.849G>T p.L283= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV100695533; called by muse, mutect2, varscan2
- HTR5A | c.156G>A p.A52= | Silent (SNP) | VAF 36/92 reads (39%) | catalogued as rs756256661, COSV55283888; called by muse, mutect2, varscan2
- PARP8 | c.1077G>A p.S359= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs549614227, COSV99891954; called by muse, varscan2
- PCDHA12 | c.1455G>A p.Q485= | Silent (SNP) | VAF 8/157 reads (5%) | catalogued as COSV100251752; called by muse, mutect2
- PI3 | c.52C>T p.L18= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV99714212; called by muse, mutect2, varscan2
- PITPNM2 | c.810C>T p.L270= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as rs755908400, COSV99759231; called by muse, mutect2, varscan2
- PRAMEF7 | c.1299G>A p.G433= | Silent (SNP) | VAF 12/336 reads (4%) | catalogued as COSV100435197; called by muse, mutect2
- SCN7A | c.3270A>T p.P1090= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV101313283; called by muse, mutect2, varscan2
- SERPINA12 | c.945C>A p.G315= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV100369729; called by muse, mutect2, varscan2
- SESN1 | c.124C>A p.R42= (on ENST00000356644 / NM_001199933.1; = p.R101= on NM_014454.3) | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as COSV100122803; called by muse, mutect2, varscan2
- SLITRK5 | c.390T>C p.G130= | Silent (SNP) | VAF 43/217 reads (20%) | catalogued as COSV100280930; called by muse, mutect2, varscan2
- SYNGR3 | c.435G>T p.A145= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV50191529; called by mutect2, varscan2
- TDRD1 | c.1518A>G p.P506= | Silent (SNP) | VAF 56/123 reads (46%) | catalogued as COSV99314737; called by muse, mutect2, varscan2
- TRIM42 | c.1029G>A p.K343= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as COSV99648522; called by muse, mutect2, varscan2
- TSPAN1 | c.168G>A p.V56= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV100915670; called by muse, mutect2, varscan2
- VEPH1 | c.2364C>T p.F788= | Silent (SNP) | VAF 35/102 reads (34%) | catalogued as rs527392367, COSV62876749; called by muse, mutect2, varscan2
- ZNF32 | c.117A>G p.T39= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as COSV100986501; called by muse, mutect2, varscan2
- ZNF84 | c.1608A>T p.T536= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- ZSWIM2 | c.1041T>C p.C347= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV99720320; called by muse, mutect2, varscan2
- ABT1 | c.-1C>T | 5'UTR (SNP) | VAF 4/15 reads (27%) | catalogued as rs138003871; called by muse, mutect2, varscan2
- ARL4A | c.-1A>C | 5'UTR (SNP) | VAF 62/208 reads (30%) | catalogued as COSV100775937; called by muse, mutect2, varscan2
- KNG1 | c.*1423C>A | 3'UTR (SNP) | VAF 7/78 reads (9%) | catalogued as COSV53976195, COSV99405669; called by muse, mutect2
- PML | c.1710+882G>A | Intron (SNP) | VAF 15/109 reads (14%) | catalogued as rs756641826, COSV51449852; called by muse, mutect2, varscan2
